Gene-level copy-number profile of tumor specimen C3L-01978-01 (profiled together with C3L-01978-03) from CPTAC case C3L-01978, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 57.4 years (20,952 days).
Specimen C3L-01978-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 33da4572-66b3-49d6-806c-364ca07b4872.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01978-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/837f8122-dce8-49d9-ae3c-cf52f8d0fe52

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,644; copy number 2: 53,248; copy number 3: 1,443; copy number 4: 62; copy number 9: 1; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:47,908,064–47,999,791, 4 genes, copy number 9–11: AC245041.2, NPY4R2, AC245041.1, FAM25C.

Autosomal genes at a single copy (total copy number 1): 1,300. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
